Somatic mutation profile of tumor specimen TCGA-E7-A5KF-01A (aliquot TCGA-E7-A5KF-01A-11D-A289-08) from TCGA case TCGA-E7-A5KF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 67.2 years (24,528 days).
Specimen TCGA-E7-A5KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61d21526-a9dc-4b25-a4cc-83a2977db9be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A5KF-10A (Blood Derived Normal), aliquot TCGA-E7-A5KF-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7e9142c-0136-4c4c-a9b4-d8673cb20cf3

The open-access MAF lists 238 somatic variants for this specimen: 165 protein-altering or splice-affecting, 68 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 68, Nonsense Mutation 15, Frame Shift Del 3, Intron 3, Frame Shift Ins 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATM | c.5515C>T p.Q1839* | Nonsense Mutation (SNP) | VAF 13/14 reads (93%) | catalogued as rs786204751, CM980143, COSV53732966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 131/275 reads (48%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7396C>G p.L2466V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV71293376; called by muse, mutect2, varscan2
- ABCA13 | c.14648C>T p.P4883L | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68950675; called by muse, mutect2, varscan2
- ABHD1 | c.87G>C p.L29F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV53151994, COSV99565473; called by muse, mutect2, varscan2
- ABHD16A | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV65452610; called by muse, mutect2, varscan2
- ADD2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV52471252; called by muse, mutect2, varscan2
- ADH6 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV52956264; called by muse, mutect2, varscan2
- AKR1C4 | c.700G>C p.V234L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV54125584; called by muse, varscan2
- ALMS1 | c.2203C>G p.Q735E | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs757152182, COSV52522002; called by muse, mutect2, varscan2
- ALMS1 | c.2582C>G p.S861C | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.818); catalogued as COSV52522011; called by muse, mutect2, varscan2
- ALMS1 | c.8796G>C p.Q2932H | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52522021; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5062G>C p.E1688Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV51858541; called by muse, mutect2, varscan2
- ANO1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 69/87 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1282388664, COSV60289166; called by muse, mutect2, varscan2
- AP1G2 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.777); catalogued as COSV58115678; called by muse, mutect2, varscan2
- AP3S1 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV57477267; called by muse, mutect2, varscan2
- ARHGAP31 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51798948; called by muse, mutect2, varscan2
- BACE2 | c.174C>G p.D58E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57741135; called by muse, mutect2
- BLM | c.2468C>G p.S823C | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as COSV61925882, COSV61927390; called by muse, mutect2, varscan2
- CASZ1 | c.2492C>T p.S831L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100681897, COSV59740993; called by muse, mutect2, varscan2
- CDKN1A | c.66del p.F22Lfs*9 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV55188640; called by mutect2, pindel, varscan2
- CENPT | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV54649899; called by muse, mutect2, varscan2
- CGNL1 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV55575228; called by muse, mutect2, varscan2
- COL28A1 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as COSV101258958, COSV68084089; called by muse, mutect2, varscan2
- COL4A3 | c.3584G>A p.G1195E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59259542; called by muse, mutect2, varscan2
- COL9A1 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61827884, COSV61837684; called by muse, mutect2, varscan2
- CORIN | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs747303237, COSV56699332; called by muse, mutect2, varscan2
- CSF1R | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs779762340, COSV53839112; called by muse, mutect2, varscan2
- CSMD3 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.971); catalogued as rs772711273, COSV52318119; called by muse, mutect2, varscan2
- CSRNP1 | c.1679C>G p.S560C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56189326, COSV56189912; called by muse, mutect2, varscan2
- CWC27 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV101126612; called by muse, mutect2, varscan2
- CYP2C8 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as rs780544107, COSV64879554; called by muse, mutect2, varscan2
- DCHS1 | c.4592C>T p.S1531L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs1454937843, COSV55038878; called by muse, mutect2, varscan2
- DDI1 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 84/85 reads (99%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV100160153, COSV56388047; called by muse, mutect2, varscan2
- DNAH7 | c.11670G>C p.Q3890H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56786281; called by muse, mutect2, varscan2
- DOP1A | c.3728G>A p.G1243E | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV52718077; called by muse, mutect2, varscan2
- DOP1A | c.5071G>C p.D1691H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52718098; called by muse, mutect2, varscan2
- DSEL | c.1900A>G p.M634V | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV59494762; called by muse, mutect2, varscan2
- DYSF | c.4999G>C p.E1667Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50584044, COSV50643751; called by muse, mutect2, varscan2
- ECT2 | c.941A>G p.E314G (on ENST00000392692 / NM_001349098.2; = p.E283G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51694148; called by muse, mutect2, varscan2
- EIF2B4 | c.416C>T p.S139L (on ENST00000347454 / NM_001034116.2; = p.S138L on NM_015636.3) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52010444, COSV99278039; called by muse, mutect2, varscan2
- EIF3M | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.971); catalogued as COSV60073567; called by muse, mutect2, varscan2
- ELF3 | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 112/155 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62840390; called by muse, mutect2, varscan2
- EPHA3 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60695708; called by muse, mutect2, varscan2
- ERP29 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV55674567; called by muse, mutect2, varscan2
- ESX1 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV65425142; called by muse, mutect2, varscan2
- FAM131B | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV68126998, COSV68127020; called by muse, mutect2, varscan2
- FAT3 | c.8698G>A p.E2900K | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV53173634; called by muse, mutect2, varscan2
- FBF1 | c.816G>C p.Q272H (on ENST00000586717; = p.Q286H on NM_001319193.1) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59867033; called by muse, mutect2, varscan2
- FBXO33 | c.524C>A p.S175* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV99981051, COSV99981102; called by muse, mutect2, varscan2
- FHOD3 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.543); catalogued as COSV57188620; called by muse, varscan2
- FRMPD1 | c.3586C>G p.Q1196E | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as rs746720540, COSV66703107; called by muse, mutect2, varscan2
- GDA | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV52997594; called by muse, mutect2, varscan2
- GNL3L | c.926C>G p.P309R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.436); catalogued as COSV60577656; called by muse, mutect2, varscan2
- GPR132 | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV61678368; called by muse, mutect2, varscan2
- GPR75 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150401369; called by muse, mutect2, varscan2
- GRID2 | c.3008G>A p.R1003Q | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs773192553, COSV56253710, COSV56265967; called by muse, mutect2, varscan2
- H2AC20 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs782778462, COSV58613200; called by muse, mutect2, varscan2
- HMCN1 | c.13396G>C p.E4466Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54941443; called by muse, mutect2, varscan2
- HNRNPU | c.1645G>C p.E549Q (on ENST00000283179; = p.E611Q on NM_004501.3) | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV51694309; called by muse, mutect2, varscan2
- HTR6 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs61733141, COSV57034647, COSV99230180; called by muse, mutect2, varscan2
- INPP4B | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99526930; called by muse, mutect2, varscan2
- IPO5 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs767414960, COSV55159843; called by muse, mutect2, varscan2
- IQGAP3 | c.4514G>A p.G1505D | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV63254627; called by muse, mutect2, varscan2
- ITCH | c.862C>G p.L288V (on ENST00000262650 / NM_001257137.3; = p.L247V on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.08); catalogued as COSV52929497, COSV52930314; called by muse, mutect2, varscan2
- KANSL1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52264650; called by muse, mutect2, varscan2
- KAT6A | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV55911954; called by muse, mutect2, varscan2
- KCNJ1 | c.1060C>G p.H354D | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100131485, COSV60662819; called by muse, mutect2, varscan2
- KCTD3 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV52070614; called by muse, mutect2
- KDM6A | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 67/67 reads (100%) | catalogued as COSV65037923; called by muse, mutect2, varscan2
- KIF14 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV66262899, COSV66264113; called by muse, mutect2, varscan2
- L3HYPDH | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV54201481; called by muse, mutect2, varscan2
- LDLR | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV52945982; called by muse, mutect2, varscan2
- LMAN2L | c.807G>C p.L269F | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV53844046; called by muse, mutect2, varscan2
- LMAN2L | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs1408410619, COSV53844060; called by muse, mutect2, varscan2
- LRP1 | c.6578C>T p.S2193L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs766547899, COSV54525773; called by muse, mutect2, varscan2
- LRP6 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53794561; called by muse, mutect2, varscan2
- LVRN | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV63498370; called by muse, mutect2, varscan2
- MGAT5B | c.2145C>A p.F715L (on ENST00000569840 / NM_001199172.2; = p.F713L on NM_144677.3) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.979); catalogued as COSV56936791; called by muse, mutect2, varscan2
- MIDEAS | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 62/136 reads (46%) | catalogued as COSV99679258; called by muse, varscan2
- MIER1 | c.277G>T p.E93* (on ENST00000355356 / NM_001077701.3; = p.E110* on NM_020948.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV100591275, COSV100591315; called by muse, mutect2, varscan2
- MZT2B | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs201764725, COSV56059907; called by muse, mutect2, varscan2
- NBN | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55377019; called by muse, mutect2, varscan2
- NBPF1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 90/484 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs771686457, COSV101236776; called by muse, varscan2
- NEFH | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV60220659; called by muse, mutect2, varscan2
- NKD1 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.136); catalogued as rs757932105, COSV51694716, COSV99194117; called by muse, mutect2, varscan2
- NRP2 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.168); catalogued as COSV55935408; called by muse, varscan2
- OBSCN | c.19160C>T p.S6387L | Missense Mutation (SNP) | VAF 67/102 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs371696980, COSV52771546; called by muse, mutect2, varscan2
- OS9 | c.1230G>C p.Q410H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV57784679; called by muse, mutect2, varscan2
- PCDH11X | c.12G>T p.L4F | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs144734965, COSV53503929; called by muse, mutect2, varscan2
- PCDHB4 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.434); catalogued as COSV52021284; called by muse, mutect2, varscan2
- PCDHB5 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50670744; called by muse, mutect2, varscan2
- PDGFRA | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.15); catalogued as COSV57264533, COSV57266146; called by muse, mutect2, varscan2
- PFN1 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52592094; called by muse, mutect2, varscan2
- PKD2L1 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV58395172, COSV58398876; called by muse, mutect2, varscan2
- PLCB1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV62068396, COSV99059791; called by muse, mutect2, varscan2
- PLEKHG6 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as COSV99165036; called by muse, mutect2, varscan2
- PLTP | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV51944947; called by muse, mutect2
- PPCS | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV65333938; called by muse, mutect2, varscan2
- PPP4R1 | c.269G>C p.R90T (on ENST00000400556 / NM_001042388.3; = p.R73T on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV53284669; called by muse, mutect2, varscan2
- PRR5 | c.799G>C p.E267Q (on ENST00000336985 / NM_181333.4; = p.E258Q on NM_015366.4) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99134936, COSV99135052; called by muse, mutect2
- PSD | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs767188702, COSV50061649; called by muse, mutect2, varscan2
- PSIP1 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 56/57 reads (98%) | catalogued as COSV101051010; called by muse, mutect2, varscan2
- PUM3 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV67397442; called by muse, mutect2, varscan2
- PURA | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.899); catalogued as COSV58762973; called by muse, mutect2, varscan2
- RANBP17 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV66657086; called by muse, mutect2, varscan2
- RETREG2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1005821509, COSV56088893; called by muse, mutect2, varscan2
- RHOB | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as COSV55355615, COSV55357131; called by muse, mutect2, varscan2
- RPTOR | c.2780G>T p.R927L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV60805001, COSV60815486; called by muse, mutect2, varscan2
- SDCCAG8 | c.729G>C p.L243F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV59417784; called by muse, mutect2, varscan2
- SLC10A2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as COSV55357572, COSV55361692; called by muse, mutect2, varscan2
- SLC23A3 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.382); catalogued as COSV55409525; called by muse, mutect2, varscan2
- SLC25A23 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51197151; called by muse, mutect2, varscan2
- SLC35C2 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV54757122; called by muse, mutect2, varscan2
- SLC4A3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs753042417, COSV56095970, COSV56097598; called by muse, mutect2, varscan2
- SMG7 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 87/143 reads (61%) | catalogued as COSV100750585; called by muse, mutect2, varscan2
- SMU1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as COSV68139475; called by muse, mutect2, varscan2
- SNAPC1 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV53521404; called by muse, mutect2, varscan2
- SNED1 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60033446; called by muse, mutect2, varscan2
- SNX20 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56059158; called by muse, mutect2, varscan2
- SPEN | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 76/309 reads (25%) | catalogued as COSV65359709; called by muse, mutect2, varscan2
- SPIRE2 | c.695C>G p.A232G | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as COSV65557656; called by muse, mutect2, varscan2
- SPOCD1 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57100024; called by muse, mutect2, varscan2
- SPRY4 | c.64C>G p.L22V (on ENST00000434127 / NM_001127496.3; = p.L45V on NM_030964.4) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV59986788; called by muse, mutect2, varscan2
- SRD5A2 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV51873710; called by muse, mutect2, varscan2
- SREK1 | c.1057del p.E353Kfs*47 | Frame Shift Del (DEL) | VAF 30/67 reads (45%) | catalogued as COSV52335193; called by pindel, varscan2
- SREK1 | c.1064G>T p.R355I | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV52335206; called by muse, varscan2
- SREK1 | c.1065A>C p.R355S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as COSV52335225; called by muse, varscan2
- STAG2 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 39/41 reads (95%) | catalogued as COSV54349879; called by muse, mutect2, varscan2
- STRC | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55853684; called by muse, mutect2, varscan2
- SUCO | c.3472T>A p.Y1158N | Missense Mutation (SNP) | VAF 127/184 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV55271290; called by muse, mutect2, varscan2
- TAF5L | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 93/129 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51091275, COSV99032947; called by muse, mutect2, varscan2
- TBC1D8 | c.2803G>A p.D935N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV51823133; called by muse, mutect2, varscan2
- TENT4B | c.1556G>A p.R519K (on ENST00000561678 / NM_001365323.2; = p.R504K on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62547688; called by muse, mutect2, varscan2
- TG | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55094009; called by muse, mutect2, varscan2
- TGFBRAP1 | c.87C>A p.C29* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV99305557; called by muse, mutect2, varscan2
- TLR5 | c.1604C>G p.S535C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.75); catalogued as COSV60560845; called by muse, mutect2, varscan2
- TMCO4 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53877320, COSV53877337; called by muse, mutect2, varscan2
- TMEM184C | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1321196926, COSV56854777; called by muse, mutect2, varscan2
- TMEM45A | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60255891; called by muse, mutect2, varscan2
- TNFAIP6 | c.539T>A p.F180Y | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54642637; called by muse, mutect2, varscan2
- TNFRSF8 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55800777; called by muse, mutect2, varscan2
- TNRC6C | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56952870; called by muse, mutect2, varscan2
- TNRC6C | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs760989909, COSV56952885; called by muse, mutect2, varscan2
- TNRC6C | c.1858G>C p.D620H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV56952899; called by muse, mutect2, varscan2
- TP53BP1 | c.3223G>C p.E1075Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.091); catalogued as COSV55509475; called by muse, mutect2, varscan2
- TSEN34 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55477617; called by muse, mutect2, varscan2
- TTBK2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51178959; called by muse, mutect2, varscan2
- UBR4 | c.10711A>G p.I3571V | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs767335189, COSV64399306; called by muse, mutect2, varscan2
- USP15 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs1447037714, COSV54798822; called by muse, mutect2, varscan2
- UTRN | c.9000G>T p.Q3000H | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100837828, COSV62305491; called by muse, mutect2, varscan2
- VPS8 | c.2854G>A p.E952K (on ENST00000625842 / NM_001349294.1; = p.E950K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV54985961; called by muse, mutect2, varscan2
- WWC2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs751858058, COSV66716764; called by muse, mutect2, varscan2
- ZBBX | c.1774C>G p.Q592E | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1204246254, COSV56791760, COSV56801465; called by muse, mutect2, varscan2
- ZBTB32 | c.1300G>T p.G434W | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV52892566; called by muse, mutect2, varscan2
- ZBTB33 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 122/125 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58535155; called by muse, mutect2, varscan2
- ZFHX4 | c.10667C>T p.S3556L | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV51451190, COSV51496144; called by muse, mutect2, varscan2
- ZNF345 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV59325297; called by muse, mutect2, varscan2
- ZNF648 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60571059; called by muse, mutect2, varscan2
- ZZEF1 | c.5470G>A p.E1824K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV101067796, COSV67560249; called by muse, mutect2
- ACACA | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM131A | c.301_307dup p.E103Afs*3 (on ENST00000310585; = p.E134Afs*3 on NM_144635.5) | Frame Shift Ins (INS) | VAF 68/191 reads (36%) | called by mutect2, varscan2
- FMR1NB | c.694del p.R232Efs*73 | Frame Shift Del (DEL) | VAF 46/64 reads (72%) | called by mutect2, pindel, varscan2
- TPTE | c.1420G>A p.D474N (on ENST00000618007 / NM_199261.4; = p.D456N on NM_199259.4) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ZNF292 | c.6988dup p.M2330Nfs*11 | Frame Shift Ins (INS) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.1626C>T p.F542= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV53164933; called by muse, mutect2, varscan2
- ADCY5 | c.2628C>T p.V876= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV59204390; called by muse, mutect2, varscan2
- ADCY5 | c.2337G>A p.Q779= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV59204403; called by muse, mutect2, varscan2
- ADD1 | c.165G>A p.K55= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as COSV53274326; called by muse, mutect2, varscan2
- APEH | c.1077C>T p.I359= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV56536804; called by muse, mutect2, varscan2
- ARL4D | c.192C>T p.L64= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs779395257, COSV60721916; called by muse, mutect2, varscan2
- CACNA1E | c.297C>T p.I99= | Silent (SNP) | VAF 39/73 reads (53%) | catalogued as COSV62424136; called by muse, mutect2, varscan2
- CAPS | c.569G>A p.*190= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99222514; called by muse, mutect2, varscan2
- CEP164 | c.877C>T p.L293= | Silent (SNP) | VAF 71/74 reads (96%) | catalogued as COSV54046298; called by muse, mutect2, varscan2
- CHD9 | c.975C>T p.I325= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV68300342; called by muse, mutect2, varscan2
- CLK2 | c.723C>T p.I241= (on ENST00000368361 / NM_001294339.2; = p.I240= on NM_003993.4) | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV56947414; called by muse, varscan2
- CNDP2 | c.729C>T p.L243= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV60841687; called by muse, mutect2, varscan2
- COG8 | c.825C>T p.I275= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs147094162; called by muse, mutect2, varscan2
- CYP4F2 | c.1419C>T p.F473= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs763963721, COSV55620509; called by muse, mutect2, varscan2
- EHHADH | c.1164G>A p.L388= | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as COSV51633536; called by muse, mutect2, varscan2
- EPHA2 | c.294C>T p.L98= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV64454556, COSV64454717; called by muse, mutect2, varscan2
- FOXK2 | c.1977G>A p.Q659= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV58882953; called by muse, mutect2, varscan2
- FRYL | c.2604G>T p.L868= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV51962354; called by muse, mutect2, varscan2
- HGD | c.216C>T p.P72= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV52201440; called by muse, mutect2
- ITGB2 | c.612C>T p.F204= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as rs1568893297, COSV100185693, COSV56610817; called by muse, mutect2, varscan2
- KALRN | c.3564G>A p.V1188= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as COSV53780318; called by muse, mutect2, varscan2
- KIF20B | c.4053G>A p.Q1351= (on ENST00000371728 / NM_001284259.2; = p.Q1311= on NM_016195.4) | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV53315432; called by muse, mutect2, varscan2
- LRRC4B | c.1470G>A p.V490= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV65350799; called by muse, mutect2, varscan2
- MAML3 | c.2001G>A p.Q667= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs6858140, COSV59077892; called by muse, mutect2, varscan2
- MCL1 | c.441C>T p.V147= | Silent (SNP) | VAF 70/164 reads (43%) | catalogued as rs768299859, COSV57190514; called by muse, mutect2, varscan2
- METRN | c.819C>T p.F273= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as COSV54799990; called by muse, mutect2, varscan2
- MRC1 | c.675G>A p.L225= | Silent (SNP) | VAF 63/144 reads (44%) | called by muse, mutect2, varscan2
- MUC16 | c.41712C>G p.V13904= | Silent (SNP) | VAF 73/188 reads (39%) | catalogued as COSV66696460; called by muse, mutect2, varscan2
- MUC5B | c.3621C>T p.F1207= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV71595517; called by muse, mutect2, varscan2
- MYO5A | c.2460C>T p.I820= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV62564745; called by muse, mutect2, varscan2
- NOMO2 | c.451C>T p.L151= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100395840; called by mutect2, varscan2
- NR1I2 | c.225G>C p.L75= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs766547239, COSV61977260, COSV61979732; called by muse, varscan2
- NR1I2 | c.309G>A p.L103= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs201488139, COSV61979738; called by muse, varscan2
- NUDT6 | c.36G>A p.A12= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV56773884, COSV56781258; called by muse, mutect2, varscan2
- OBSCN | c.20475C>T p.F6825= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs1558421247, COSV63468599; called by muse, mutect2, varscan2
- OR2T12 | c.600C>T p.C200= | Silent (SNP) | VAF 88/140 reads (63%) | catalogued as COSV58779536; called by muse, mutect2, varscan2
- PALD1 | c.1425G>A p.P475= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs371642744; called by muse, mutect2, varscan2
- PCDH17 | c.639G>A p.L213= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV64979193; called by muse, mutect2, varscan2
- PCDH17 | c.3033C>A p.L1011= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV64973420, COSV64979203; called by muse, mutect2, varscan2
- PCDHAC2 | c.2316C>G p.L772= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV53869787; called by muse, mutect2, varscan2
- PCDHB5 | c.1716C>A p.T572= | Silent (SNP) | VAF 91/203 reads (45%) | catalogued as COSV50668682, COSV50670796; called by muse, mutect2, varscan2
- PCDHB5 | c.1887G>T p.L629= | Silent (SNP) | VAF 70/170 reads (41%) | catalogued as COSV50670835; called by muse, mutect2, varscan2
- PCMTD1 | c.228G>A p.L76= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV62125699; called by muse, mutect2, varscan2
- PDE8B | c.2595C>T p.Y865= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV53745475; called by muse, mutect2, varscan2
- PI16 | c.810G>T p.T270= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as COSV101010144, COSV65321451; called by muse, mutect2, varscan2
- PIGG | c.1746G>A p.V582= (on ENST00000453061 / NM_001127178.3; = p.V574= on NM_017733.4) | Silent (SNP) | VAF 77/159 reads (48%) | catalogued as COSV56321452; called by muse, mutect2, varscan2
- PPP1R12B | c.459C>G p.V153= | Silent (SNP) | VAF 101/144 reads (70%) | catalogued as COSV61123773; called by muse, mutect2, varscan2
- PRR5 | c.246C>T p.F82= (on ENST00000336985 / NM_181333.4; = p.F73= on NM_015366.4) | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV50063822; called by muse, mutect2, varscan2
- PTPN13 | c.2679C>T p.L893= | Silent (SNP) | VAF 95/220 reads (43%) | catalogued as COSV57411653; called by muse, mutect2, varscan2
- REV3L | c.1500C>T p.D500= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs779920170, COSV62623439; called by muse, mutect2, varscan2
- RNF123 | c.3090C>T p.L1030= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV57540153; called by muse, mutect2, varscan2
- RPTOR | c.2781G>T p.R927= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV60818396; called by muse, mutect2, varscan2
- SERPIND1 | c.129G>A p.E43= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV53140854; called by muse, mutect2, varscan2
- SLC22A7 | c.276C>T p.T92= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV65356389; called by muse, mutect2, varscan2
- SNRK | c.1887C>G p.P629= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV56070843; called by muse, mutect2, varscan2
- SUGP2 | c.1377C>A p.L459= | Silent (SNP) | VAF 47/298 reads (16%) | catalogued as COSV58265287; called by muse, mutect2, varscan2
- SYCN | c.387C>G p.L129= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV59213155; called by muse, mutect2, varscan2
- SYNRG | c.2445C>T p.L815= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as rs776514616; called by muse, mutect2, varscan2
- SZT2 | c.3333C>G p.L1111= (on ENST00000634258 / NM_001365999.1; = p.L1054= on NM_015284.4) | Silent (SNP) | VAF 62/147 reads (42%) | catalogued as COSV65174518; called by muse, varscan2
- TDRD5 | c.2945G>A p.*982= | Silent (SNP) | VAF 49/79 reads (62%) | catalogued as COSV99677221; called by muse, mutect2, varscan2
- TET3 | c.5223G>A p.G1741= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs777910245, COSV69645638; called by muse, mutect2, varscan2
- TOB2 | c.300C>T p.S100= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs528142533, COSV59501771; called by muse, mutect2, varscan2
- TRIM61 | c.321C>T p.F107= | Silent (SNP) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- TRPV1 | c.1980C>T p.F660= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV51518535; called by muse, mutect2, varscan2
- TTC9 | c.561G>C p.L187= | Silent (SNP) | VAF 87/185 reads (47%) | catalogued as COSV56449162, COSV99832809; called by muse, mutect2, varscan2
- TTI1 | c.2313C>T p.F771= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV65063589; called by muse, mutect2, varscan2
- VPS13D | c.11841C>G p.L3947= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV50683983; called by muse, mutect2, varscan2
- WT1 | c.1425G>A p.Q475= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as COSV60083724; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827602 G>A | 3'Flank (SNP) | VAF 12/12 reads (100%) | catalogued as rs746310444; called by muse, varscan2
- DLG3 | c.1145+700C>T | Intron (SNP) | VAF 26/26 reads (100%) | catalogued as COSV52087219; called by muse, mutect2, varscan2
- SEPTIN5 | c.55-1114G>A | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100820470; called by muse, mutect2, varscan2
- STK3 | c.352-15557A>G | Intron (SNP) | VAF 21/37 reads (57%) | catalogued as rs1170362083; called by muse, mutect2, varscan2
